Gene-level copy-number profile of tumor specimen TARGET-40-PARKAF-01A from TARGET case TARGET-40-PARKAF, project TARGET-OS (Osteosarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 16.7 years (6,085 days).
Specimen TARGET-40-PARKAF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-OS.049345c9-954d-573f-99ed-0dd640037fd8.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-40-PARKAF-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 408 have no estimate.
https://portal.gdc.cancer.gov/files/772296c8-4bad-48c9-96ca-9d2581ab9e8a

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,105; copy number 1: 2,810; copy number 2: 19,629; copy number 3: 14,918; copy number 4: 14,962; copy number 5: 3,901; copy number 6: 1,252; copy number 7: 516; copy number 8: 200; copy number 9: 157; copy number 10: 242; copy number 11: 97; copy number 12: 112; copy number 13: 148; copy number 14: 70; copy number 15: 42; copy number 17: 22; copy number 18: 11; copy number 21: 5; copy number 22: 8; copy number 25: 7; copy number 27: 1.

Homozygous deletions (total copy number 0; autosomes only): 62 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:116,552,473–117,027,039, 10 genes: LINC00903, RN7SL582P, BZW1P2, TUSC7, AC108713.1, MIR4447, AC069504.1, LINC00901, RNU5E-8P, PTMAP8.
- chr3:175,059,361–175,115,242, 2 genes: EEF1B2P8, NAALADL2-AS3.
- chr9:20,999,509–21,422,960, 30 genes: HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2.
- chr9:21,638,285–22,214,672, 18 genes: H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.
- chr17:18,450,244–18,475,920, 2 genes (within-gene range 0–4): KRT16P4, TNPO1P2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 6,791 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,636,547–81,992,436, 123 genes, copy number 5–6 (within-gene range 4–6) (broad region; genes not listed).
- chr1:143,541,768–147,517,875, 130 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr1:166,763,334–180,204,030, 277 genes, copy number 5–11 (within-gene range 4–11) (broad region; genes not listed).
- chr1:203,626,787–204,377,665, 26 genes, copy number 5–6 (within-gene range 2–6): ATP2B4, NSA2P1, SNORA77, LAX1, ZC3H11A, ZBED6, AC114402.2, AC114402.1, RPL35AP5, SNRPE, KRT8P29, HSPE1P6, CBX1P3, AC096645.1, LINC00303, AL592146.2, SOX13, AL592146.1, ETNK2, ERLNC1, REN, AL592114.2, KISS1, GOLT1A, PLEKHA6, AL592114.3.
- chr2:421,057–4,827,084, 64 genes, copy number 6 (broad region; genes not listed).
- chr2:5,313,740–40,255,209, 598 genes, copy number 5–7 (broad region; genes not listed).
- chr4:37,866,561–40,811,184, 73 genes, copy number 5 (broad region; genes not listed).
- chr4:78,632,273–89,841,978, 177 genes, copy number 5–18 (broad region; genes not listed).
- chr4:155,666,726–169,975,904, 169 genes, copy number 8–17 (within-gene range 3–17) (broad region; genes not listed).
- chr4:170,060,222–176,014,417, 68 genes, copy number 10–13 (broad region; genes not listed).
- chr4:184,910,889–187,060,930, 49 genes, copy number 12: AC084871.2, MIR4455, AC112243.1, LINC02437, HELT, LINC02436, AC093824.1, AC093824.2, SLC25A4, CFAP97, SNX25, LRP2BP, AC112722.1, ANKRD37, UFSP2, Y_RNA, C4orf47, CCDC110, AC106897.1, PDLIM3, SORBS2, AC093797.1, AC108472.1, Y_RNA, AC104805.1, AC096659.1, RNU4-64P, TLR3, FAM149A, AC104070.1, RPSAP70, ORAOV1P1, FLJ38576, CYP4V2, KLKB1, F11, F11-AS1, AC109517.1, SLC25A5P6, AC018709.1, RNU6-1055P, MTNR1A, FAT1, AC107050.1, AC108865.1, AC108865.2, MRPS36P2, AC110772.1, AC110772.2.
- chr5:31,400,497–40,067,200, 158 genes, copy number 6–7 (broad region; genes not listed).
- chr5:40,415,137–43,067,452, 49 genes, copy number 6 (within-gene range 2–6): AC093277.1, AC114977.1, AC114977.2, TTC33, SNORA63, PTGER4, PRKAA1, AC008810.1, RPL37, SNORD72, CARD6, C7, RNU7-161P, AC114967.1, MROH2B, C6, PLCXD3, AC008817.1, OXCT1, AC034222.2, OXCT1-AS1, AC034222.1, C5orf51, FBXO4, RPSAP38, Y_RNA, MTHFD2P6, AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2.
- chr5:147,234,963–149,722,372, 58 genes, copy number 5 (within-gene range 4–5): STK32A, DPYSL3, AC011373.1, JAKMIP2-AS1, JAKMIP2, AC011370.1, SPINK1, AC011352.2, SCGB3A2, C5orf46, AC011352.1, AC011352.3, EEF1GP2, SPINK5, AC011346.1, SPINK14, SPINK6, HMGN1P16, MARCOL, SPINK13, PGBD4P3, SPINK7, SPINK9, AC091948.1, FBXO38, Metazoa_SRP, AC114939.1, HTR4, AC008627.1, ADRB2, SH3TC2, AC116312.1, RNU6-732P, MIR584, SH3TC2-DT, RN7SKP145, ABLIM3, AC012613.1, AC012613.2, AFAP1L1, AC131025.3, GRPEL2, GRPEL2-AS1, PCYOX1L, IL17B, AC131025.1, CARMN, AC131025.2, MIR143, MIR145, CSNK1A1, AC021078.1, RPL29P14, ARHGEF37, RNU6-588P, AC022100.1, U3, RN7SL868P.
- chr5:151,366,299–166,029,311, 187 genes, copy number 5–6 (broad region; genes not listed).
- chr5:166,382,305–170,814,047, 54 genes, copy number 5: AC026403.1, LINC01947, AC091819.2, AC091819.1, TENM2, AC091820.2, AC091820.1, AC008601.1, AC008708.2, AC008708.1, AC008464.1, AC008705.2, AC008705.1, AC011369.1, AC011369.2, CTB-178M22.2, WWC1, RARS1, FBLL1, PANK3, SLC2A3P1, MIR103A1, MIR103B1, RPL10P9, AC011365.1, SLIT3, SLIT3-AS2, MIR218-2, Y_RNA, AC011389.1, AC011389.2, SLIT3-AS1, MIR585, RNU6-477P, SPDL1, DOCK2, AC008680.1, INSYN2B, MIR378E, FOXI1, KRT18P41, LINC01187, C5orf58, LCP2, AC034199.2, LINC01366, AC034199.1, KCNIP1, KCNMB1, KCNIP1-OT1, AC008619.1, KCNIP1-AS1, AC008514.1, GABRP.
- chr6:41,026,895–42,050,357, 46 genes, copy number 5 (within-gene range 4–5): UNC5CL, OARD1, TSPO2, APOBEC2, NFYA, AL031778.1, ADCY10P1, TREML1, TREM2, TREML2, TREML3P, TREML4, RNA5SP207, TREML5P, AL391903.2, AL391903.3, TREM1, AL391903.1, RNU6-643P, AL672212.1, NCR2, AL136967.1, AL136967.2, FOXP4-AS1, LINC01276, FOXP4, MIR4641, MDFI, NPM1P51, TFEB, AL035588.1, PGC, AL365205.4, FRS3, AL365205.1, PRICKLE4, TOMM6, USP49, AL365205.3, AL365205.2, AL160163.1, MED20, Y_RNA, BYSL, CCND3, RNU6-761P.
- chr6:44,513,262–48,214,794, 50 genes, copy number 5–6: AL136140.1, AL136140.2, AL133334.1, SUPT3H, NUDT19P4, AL138880.2, RBM22P4, AL138880.1, MIR586, RUNX2, AL096865.1, RUNX2-AS1, CLIC5, RNU6-754P, AL035701.1, ENPP4, ENPP5, ACTG1P9, RCAN2, AL359633.1, AL035670.1, CYP39A1, SLC25A27, AL591242.1, TDRD6, PLA2G7, ANKRD66, AL161618.1, MEP1A, ADGRF5, ADGRF5-AS1, ADGRF1, TNFRSF21, B3GNTL1P2, AL451166.1, AL355353.1, CD2AP, Y_RNA, AL358178.1, ADGRF2, ADGRF4, RN7SKP116, AL356421.2, AL356421.1, OPN5, RNU1-105P, PTCHD4, AL353138.1, HNRNPA3P4, RBMXP1.
- chr6:56,056,590–58,438,364, 33 genes, copy number 5–7 (within-gene range 2–7): COL21A1, DHFRP6, AL031779.1, RCC2P7, DST, DST-AS1, RPL17P26, RNU6-626P, BEND6, OSTCP6, FTH1P15, MRPL30P1, KIAA1586, ZNF451, ZNF451-AS1, BAG2, RAB23, PRIM2, MIR548U, FO680682.1, AL021368.3, AL021368.5, AL021368.1, AL021368.2, GUSBP4, AL021368.4, POM121L14P, LINC00680, AL445250.1, GAPDHP15, AL390237.1, RBBP4P4, AL603755.1.
- chr7:70,972–27,185,232, 458 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr7:56,631,739–62,275,678, 76 genes, copy number 5 (broad region; genes not listed).
- chr8:150,584–5,854,977, 77 genes, copy number 6–10 (broad region; genes not listed).
- chr8:10,482,878–11,760,002, 42 genes, copy number 5–10 (within-gene range 3–10): PRSS51, AC104964.3, PRSS55, RP1L1, MIR4286, C8orf74, RNA5SP252, SOX7, AC105001.2, AC105001.1, PINX1, MIR1322, AC011008.1, AC011008.2, XKR6, MIR598, AF131215.3, AF131215.6, AF131215.5, AF131215.4, AF131215.2, AF131215.1, AF131215.7, LINC00529, RPL19P13, AF131216.2, AF131216.4, MTMR9, AF131216.1, SLC35G5, TDH, AF131216.3, FAM167A-AS1, RN7SL293P, RNU6-1084P, FAM167A, AF131216.5, BLK, AC022239.1, LINC00208, AC022239.2, GATA4.
- chr8:144,148,016–145,066,685, 61 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr9:14,475–11,013,096, 155 genes, copy number 7–27 (broad region; genes not listed).
- chr9:12,098,660–20,995,955, 109 genes, copy number 6–25 (within-gene range 0–25) (broad region; genes not listed).
- chr9:22,446,824–30,575,012, 64 genes, copy number 6–10 (broad region; genes not listed).
- chr11:65,961,728–85,627,922, 537 genes, copy number 5–7 (within-gene range 3–7) (broad region; genes not listed).
- chr11:84,997,226–109,823,893, 414 genes, copy number 5–6 (broad region; genes not listed).
- chr12:24,212,421–34,249,958, 216 genes, copy number 5 (broad region; genes not listed).
- chr12:38,906,451–41,072,415, 25 genes, copy number 10–21 (within-gene range 2–21): CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.4, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1, MUC19, AC107023.1, RNU6-713P, CNTN1, AC016144.1.
- chr13:77,417,821–81,691,072, 55 genes, copy number 5: AL159158.1, SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, AL450447.1, SLAIN1, MIR3665, EDNRB-AS1, EDNRB, OBI1-AS1, AL139002.1, RN7SL810P, LINC01069, LINC00446, AL138957.1, SRGNP1, RNY3P3, RPL31P54, ELOCP23, AL445209.1, POU4F1, OBI1, RPL21P111, LINC00331, HSPD1P8, CCT5P2, NIPA2P5, BCAS2P3, RBM26, RNA5SP33, RBM26-AS1, NDFIP2-AS1, NDFIP2, LINC01068, AL136442.1, LINC01038, LINC00382, AL158064.1, LINC01080, AL137781.1, SPRY2, RNU6-61P, HNRNPA1P31, PWWP2AP1, AL590807.1, ARF4P4, LINC00377, DPPA3P3, LINC00564, AL353633.1, RNU6-77P, HIGD1AP2, PTMAP5.
- chr14:105,785,505–106,875,071, 184 genes, copy number 5–10 (broad region; genes not listed).
- chr15:95,990,582–98,087,384, 43 genes, copy number 5: AC012409.2, AC024337.1, AC024337.2, NR2F2-AS1, AC012409.5, AC012409.3, AC012409.1, AC012409.4, LINC02157, AC016251.1, NR2F2, MIR1469, AC103746.1, AC087477.2, TUBAP12, AC087477.5, AC087477.3, PGAM1P12, AC087477.1, AC087477.4, RN7SKP254, Metazoa_SRP, AC110588.1, FAM149B1P1, SPATA8-AS1, SPATA8, RN7SKP181, LINC02253, AC020704.1, LINC02254, RN7SL677P, RNA5SP401, AC026523.2, AC026523.1, AC026523.3, AC026523.4, LINC00923, AC024651.2, AC024651.3, ARRDC4, AC024651.1, LINC02251, U6.
- chr18:14,143,596–15,330,282, 46 genes, copy number 5 (within-gene range 4–5): AC006557.2, NF1P5, ANKRD20A5P, RNU6-316P, RHOT1P1, AP005212.4, AP005212.2, CYP4F35P, AP005212.3, AP005212.1, TERF1P2, FEM1AP2, AP006261.1, LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.
- chr19:28,790,812–30,713,538, 40 genes, copy number 5: MAN1A2P1, AC007795.1, LINC00906, AC008991.1, AC011524.1, AC011524.2, RNA5SP470, LINC01532, AC011505.1, UQCRFS1, AC007786.1, AC007786.2, AC007786.3, RN7SL340P, AC007786.4, AC011474.1, AC011474.3, AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1, C19orf12, AC008798.3, CCNE1, AC008798.2, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1, AC008507.4, AC008507.5, AC005597.1, ZNF536, AC011504.1, AC011478.1.
- chr21:12,999,676–15,627,342, 70 genes, copy number 6–7 (broad region; genes not listed).
- chr21:18,269,116–46,665,124, 625 genes, copy number 5 (broad region; genes not listed).
- chr22:18,773,665–37,776,556, 816 genes, copy number 5 (broad region; genes not listed).
- chr22:46,541,495–50,486,440, 81 genes, copy number 5–6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,504. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
